Gene-level copy-number profile of tumor specimen C3N-03480-01 from CPTAC case C3N-03480, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.0 years (21,561 days).
Specimen C3N-03480-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1791565c-3851-4b41-9315-093ef3cd85df.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03480-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/4d3238f5-4d4d-4e6e-a63d-9cb5e894e0d7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 10,124; copy number 2: 48,770; copy number 3: 9.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:73,537,143–73,543,796, 2 genes (within-gene range 0–1): ACOT1, NT5CP2.
- chr17:16,786,489–16,845,881, 10 genes (within-gene range 0–2): USP32P1, SRP68P1, AC098850.4, AC098850.1, FAM106C, AC022596.1, NOS2P4, KRT16P6, KRT16P2, KRT17P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,269. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
